Gene-level copy-number profile of tumor specimen TCGA-OR-A5JG-01A from TCGA case TCGA-OR-A5JG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.3 years (22,390 days).
Specimen TCGA-OR-A5JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.73e72d55-f8ea-4f06-b439-62a6d5a81164.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c1f55662-8348-4af7-9605-89bc87f8665c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 5,776; copy number 3: 22,753; copy number 4: 9,895; copy number 5: 6,830; copy number 6: 13,783; copy number 7: 776.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JG-01A-11D-A29H-01): tumor purity 0.76, ploidy 5.68, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:71,570,956–71,573,558, 1 gene: AL354949.1.
- chr4:181,260,442–181,265,145, 1 gene: LINC02500.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 776 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–43,045,120, 776 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
